FM case AD9828 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/757e4561-18c4-4b27-9d65-2cad8481fe49

Female, 46.1 years: Papillary carcinoma, NOS (ICD-O-3 8050/3) of the thyroid gland; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
